Surgical pathology report (de-identified scan), TCGA case TCGA-DX-A6BH, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-A6BH-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED]

....

Clinical Diagnosis & History:

year old male with history of left pelvic tumor status post incomplete resection

Specimens Submitted:

- 1: Radical resection of the left pelvic mass, left testicle, spermatic cord, left external iliac artery and vein, left psoas
- 2: Final left external iliac artery margin

DIAGNOSIS:

1. Pelvis, left pelvic mass, left testicle, spermatic cord, left external iliac artery and vein, left psoas, radical resection:
- Dedifferentiated liposarcoma arising in a background of well differentiated liposarcoma.
- Tumor measures at least 8.0 cm in greatest dimension.
- Dedifferentiated component constitutes 80% of tumor and is a high grade pleomorphic sarcoma.
- Well differentiated liposarcoma, lipoma-like and sclerosing type, involving spermatic cord.
- Tumor envelops the external iliac vessels.
- Tumor extends to superior, anterior, medial and lateral margins of resection.
- External iliac artery and vein encased by liposarcoma
- Three benign lymph nodes (0/3).
- Unremarkable testis.
2. Final left external iliac artery margin, biopsy:
- Well-differentiated liposarcoma, with cautery artifact.

Note: Previous biopsy material was reviewed.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

** Continued on next page **

ICD-O-3

Liposarcoma, dedifferentiated
8858/3

Date C&F
Retrospectum C48.0

path
Connective, subcutaneous
and other soft tissues
of pelvis C49.5

9/25/13

[page 2 of 3]
SURGICAL [REDACTED]
[REDACTED]
[REDACTED]
[REDACTED]
[REDACTED]

[REDACTED]
[REDACTED]
[REDACTED]
[REDACTED]
[REDACTED]

----- Page 2 of 3

*** Report Electronically Signed Out ***

Gross Description:

The specimen is received in formalin and subsequently placed in formalin labelled "Radical resection of the left pelvic mass, left testicle, spermatic cord, left external iliac artery and vein and left psoas" and consists of a soft tissue mass measuring in toto 15 x 11 x 9 cm. The specimen is oriented using anatomic landmarks. There is a spermatic cord present measuring 22 cm in length and 2 cm in diameter. The tunica vaginalis is opened to reveal the testes (4.5 x 3.5 x 2 cm) and epididymis (4 x 0.8 x 0.8). The specimen is inked as follows: anterior-black, posterior-blue, lateral-green, medial-yellow, superior-orange and inferior-red. The spermatic cord and testicular tunics (external aspect) are inked black. The specimen is incised to reveal an 8 x 6.5 x 6.4 firm yellow soft tissue mass which encases the iliac artery and vein at the periphery. The tumor is 0.5 cm from the superior margin. The testis is incised to reveal normal, stringy testicular parenchyma. Incision of the spermatic cord approximately 15 cm proximal to the testis shows small tumor nodules measuring 1.2 cm in greatest dimension. Tumor is submitted for TPS. Pictures are obtained. Representative sections are submitted for permanent section.

Summary of sections:

AM-anterior margin
PM-posterior margin
SM-superior margin with main tumor mass
IM-inferior margin
LM-lateral margin
MM-medial margin
T-main tumor
ST-distal spermatic cord
SC-proximal spermatic cord
TE-testis
VS-iliac vessels and sarcoma
C-cystic area
S-skin

2) The specimen is received in formalin, labeled "Final left external iliac artery margin", and consists of a 0.8 x 0.5 x 0.4 cm fragment of tan soft tissue. The stitch area is inked black. The specimen is bisected and entirely submitted.

Summary of sections:

U - undesignated

** Continued on next page **

[page 3 of 3]
SURGICAL

Page 3 of 3

Summary of Sections:

Part 1: Radical resection of the left pelvic mass, left testicle, spermatic cord, left external iliac artery and vein, left psoas

Block	Sect.	Site	PCs
2		AM	2
2		C	2
2		IM	2
2		LM	2
2		MM	2
2		PM	2
1		S	1
2		SC	2
2		SM	2
2		ST	2
7		T	7
3		VS	5

Part 2: Final left external iliac artery margin

Block	Sect.	Site	PCs
1		U	3

** End of Report **

Criteria	lw 5/5/13	Yes	No

Source: NCI Genomic Data Commons file 7e5c07e1-26ac-4eb3-9d35-8eb205038d61 (TCGA-DX-A6BH.5117ACC2-7CA7-4C5B-9224-8E49D0BCDC38.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).